Somatic mutation profile of tumor specimen MBCProject_6109_T1B_WES (aliquot MBCProject_6109_T1B_WES_1) from CMI case MBCProject_6109, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.0 years (11,672 days).
Specimen MBCProject_6109_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e138254e-c68c-44d0-a22c-672183d11f84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6109_SALIVA_2 (Saliva), aliquot MBCProject_6109_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cbb236d-fb69-415b-af58-4ba86c3eb0db

The open-access MAF lists 121 somatic variants for this specimen: 87 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 22, Intron 7, In Frame Del 2, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, 5'Flank 1, 5'UTR 1, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.916-6C>T | Splice Region (SNP) | VAF 23/89 reads (26%) | catalogued as COSV55537053; called by muse, mutect2, varscan2
- ACAN | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs368584197, COSV61358168; called by muse, mutect2, varscan2
- AKAP3 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 91/515 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1315128634; called by muse, mutect2, varscan2
- ARAP2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV58292911; called by muse, mutect2, varscan2
- DOK3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57253359; called by muse, mutect2, varscan2
- EMILIN1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs552677456; called by muse, mutect2, varscan2
- FAM47B | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.073); catalogued as COSV61457262; called by muse, mutect2, varscan2
- FGD1 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.012); catalogued as COSV100910847; called by muse, mutect2, varscan2
- FGF17 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1490033943; called by muse, mutect2, varscan2
- GATA3 | c.1003dup p.D335Gfs*17 | Frame Shift Ins (INS) | VAF 354/1132 reads (31%) | catalogued as COSV60519609; called by mutect2, pindel, varscan2
- HDAC7 | c.1832G>A p.R611Q (on ENST00000427332; = p.R650Q on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs539537344; called by muse, mutect2
- IGDCC3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1344408428, COSV99080057; called by muse, mutect2, varscan2
- INVS | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 186/692 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs761806481, COSV99318409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 120/668 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs370557951, COSV100069359; called by muse, mutect2, varscan2
- KIDINS220 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs775892620, COSV56750260; called by muse, mutect2, varscan2
- LAS1L | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 66/1139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56706547; called by muse, mutect2
- MBD1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 141/612 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as rs761273021; called by muse, mutect2, varscan2
- MIOS | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 71/445 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as rs1415225705; called by muse, mutect2, varscan2
- MMP16 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 134/1134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54170667; called by muse, mutect2, varscan2
- MUC17 | c.4894C>G p.L1632V | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100075111; called by muse, mutect2, varscan2
- NFIC | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59411588; called by muse, mutect2, varscan2
- OR2G3 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773500214, COSV100180809; called by muse, mutect2, varscan2
- OTOA | c.2120C>T p.P707L (on ENST00000286149; = p.P693L on NM_144672.4) | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs781268163, COSV53753370; called by muse, mutect2, varscan2
- PCCA | c.1746+1G>C p.X582_splice | Splice Site (SNP) | VAF 77/505 reads (15%) | catalogued as CS149405; called by muse, mutect2, varscan2
- PLXNC1 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 101/729 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1285465118; called by muse, mutect2, varscan2
- PRKAR1B | c.782A>T p.K261M | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs780449319; called by muse, mutect2, varscan2
- PRKD2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV52190305; called by muse, mutect2, varscan2
- PTPRD | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 154/725 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV61989323; called by muse, mutect2, varscan2
- RAB3A | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1277045113, COSV55852042; called by muse, mutect2, varscan2
- SEMA6B | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs755696579, COSV56704146; called by muse, mutect2, varscan2
- SLC3A1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1332579288, COSV53221877; called by muse, mutect2, varscan2
- SPDYE4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1463425414, COSV104409726; called by muse, mutect2, varscan2
- SPTBN4 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs577000571; called by muse, mutect2, varscan2
- STOML3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 278/692 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1318298606, COSV65511162; called by muse, mutect2, varscan2
- SVIL | c.5489C>T p.A1830V (on ENST00000355867 / NM_021738.3; = p.A1404V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/789 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs955294945, COSV63439412; called by muse, mutect2, varscan2
- THAP3 | c.607C>T p.R203W (on ENST00000054650 / NM_001195753.1; = p.R202W on NM_001195752.1) | Missense Mutation (SNP) | VAF 102/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs545814166; called by muse, mutect2, varscan2
- ZNF135 | c.1195C>T p.Q399* (on ENST00000313434 / NM_001289401.2; = p.Q411* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 94/426 reads (22%) | catalogued as COSV57881948; called by muse, mutect2, varscan2
- ZNF579 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1236250229; called by muse, mutect2, varscan2
- ZXDB | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs768725517; called by muse, mutect2, varscan2
- ABCC6 | c.2856C>A p.F952L | Missense Mutation (SNP) | VAF 124/516 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AFP | c.400G>C p.A134P | Missense Mutation (SNP) | VAF 112/1367 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- AGO1 | c.2226T>G p.F742L | Missense Mutation (SNP) | VAF 99/512 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APC | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- C12orf29 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 125/605 reads (21%) | called by muse, mutect2, varscan2
- CCDC168 | c.7035G>T p.E2345D | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CDH7 | c.1736C>A p.T579N | Missense Mutation (SNP) | VAF 204/999 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- COG2 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 115/746 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CSPP1 | c.1339G>A p.E447K (on ENST00000676605; = p.E406K on NM_024790.6) | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- DGKD | c.1323G>C p.K441N (on ENST00000264057 / NM_152879.3; = p.K397N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAJC17 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 124/470 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DNAJC17 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 124/468 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ELFN1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM135A | c.3865C>A p.Q1289K (on ENST00000370479 / NM_001351599.1; = p.Q1076K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGFBP2 | c.236_237dup p.M80Afs*21 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- GANC | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 41/209 reads (20%) | PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRIG1 | c.573_584del p.T192_L195del | In Frame Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- LYVE1 | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- LZIC | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEA10 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTMR4 | c.2817_2820del p.K940Rfs*19 | Frame Shift Del (DEL) | VAF 221/1643 reads (13%) | called by mutect2, pindel, varscan2
- MXRA5 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEFH | c.2806G>C p.A936P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NFE2L1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 47/1490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUP210L | c.3466G>A p.V1156I | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NXNL2 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLIG2 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.132); called by muse, mutect2
- PACS1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 120/549 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- POLK | c.1976T>A p.F659Y | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRTG | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAD23A | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RC3H1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- REXO5 | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KA3 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SCCPDH | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.1105A>C p.S369R | Missense Mutation (SNP) | VAF 104/545 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SETDB1 | c.1679C>G p.A560G | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC26A7 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 109/455 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35F3 | c.142G>A p.G48S (on ENST00000366617 / NM_001300845.1; = p.G117S on NM_173508.4) | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- SOGA3 | c.2670C>A p.D890E | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPTA1 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 159/1196 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TNPO3 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- TRAM1L1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- VAV3 | c.1013_1015del p.L338del | In Frame Del (DEL) | VAF 42/176 reads (24%) | called by pindel, varscan2
- WAS | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- WNT2 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB7B | c.1297C>T p.H433Y (on ENST00000292176; = p.H467Y on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNHIT2 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- B4GAT1 | c.819C>T p.N273= | Silent (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- BAG6 | c.2322C>T p.L774= (on ENST00000676571; = p.L727= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as rs1448011022; called by muse, mutect2, varscan2
- CEACAM3 | c.666C>T p.N222= | Silent (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- CKAP4 | c.1416G>A p.V472= | Silent (SNP) | VAF 45/74 reads (61%) | called by muse, mutect2, varscan2
- ESX1 | c.180C>T p.N60= | Silent (SNP) | VAF 82/360 reads (23%) | catalogued as COSV65424182; called by muse, mutect2, varscan2
- FFAR1 | c.360G>A p.P120= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as COSV50054796; called by muse, mutect2, varscan2
- GPR162 | c.258C>T p.N86= | Silent (SNP) | VAF 38/406 reads (9%) | catalogued as rs1377735189, COSV50592391; called by muse, mutect2, varscan2
- HYDIN | c.5733G>A p.K1911= | Silent (SNP) | VAF 61/261 reads (23%) | called by mutect2, varscan2
- IL1RAP | c.240G>A p.E80= | Silent (SNP) | VAF 623/1148 reads (54%) | called by muse, mutect2, varscan2
- LMNB2 | c.966C>T p.S322= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs147230681; called by muse, mutect2, varscan2
- NRTN | c.375G>T p.V125= | Silent (SNP) | VAF 20/172 reads (12%) | called by mutect2, varscan2
- NTN5 | c.1179C>T p.A393= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs1310298271; called by muse, mutect2, varscan2
- RBPJ | c.267C>T p.R89= | Silent (SNP) | VAF 70/406 reads (17%) | catalogued as rs761169357; called by muse, mutect2, varscan2
- RGS8 | c.393G>C p.T131= (on ENST00000367556 / NM_001369564.2; = p.T149= on NM_033345.3) | Silent (SNP) | VAF 70/434 reads (16%) | called by muse, mutect2, varscan2
- SHCBP1L | c.147G>A p.S49= | Silent (SNP) | VAF 48/244 reads (20%) | catalogued as rs769813446; called by muse, varscan2
- SHOX | c.798C>T p.A266= | Silent (SNP) | VAF 49/250 reads (20%) | called by muse, mutect2, varscan2
- SLC25A14 | c.807C>T p.I269= | Silent (SNP) | VAF 105/573 reads (18%) | catalogued as rs376247628, COSV54417352; called by muse, mutect2, varscan2
- TBC1D4 | c.1317G>A p.T439= | Silent (SNP) | VAF 218/1045 reads (21%) | catalogued as rs1262636724; called by muse, mutect2, varscan2
- TEP1 | c.1947T>A p.G649= | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as COSV99401806; called by muse, mutect2, varscan2
- TRAK1 | c.2112G>A p.L704= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs528706359; called by muse, varscan2
- YME1L1 | c.993C>A p.V331= (on ENST00000326799 / NM_139312.3; = p.V274= on NM_014263.4) | Silent (SNP) | VAF 93/288 reads (32%) | catalogued as rs538552104; called by muse, mutect2, varscan2
- ZFHX2 | c.4434C>T p.D1478= | Silent (SNP) | VAF 48/218 reads (22%) | called by muse, mutect2, varscan2
- ATPAF1 | c.588+19C>G | Intron (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- CBFA2T3 | c.151+25430C>T | Intron (SNP) | VAF 117/534 reads (22%) | catalogued as rs879110606; called by muse, mutect2, varscan2
- DNPH1 | c.196+92C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, varscan2
- EPB41L1 | c.1669-2249A>C | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- FAM72A | chr1:206203882 G>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- GOLGA6L10 | c.*26_*27insC | 3'UTR (INS) | VAF 113/945 reads (12%) | called by mutect2, pindel, varscan2
- IQSEC1 | c.2847+1494G>C | Intron (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- MED12 | c.2542-10C>A | Intron (SNP) | VAF 99/533 reads (19%) | called by muse, mutect2, varscan2
- NBPF7 | n.577G>C | RNA (SNP) | VAF 63/337 reads (19%) | called by muse, mutect2, varscan2
- NEURL1B | c.-74G>C | 5'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- UNC93B1 | c.238+9C>G | Intron (SNP) | VAF 29/165 reads (18%) | catalogued as rs1054185641; called by muse, mutect2, varscan2
- ZNF843 | chr16:31434958 T>C | 3'Flank (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
